Somatic mutation profile of tumor specimen MMRF_2836_1_BM_CD138pos (aliquot MMRF_2836_1_BM_CD138pos_T1_KHS5U_L16570) from MMRF case MMRF_2836, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.3 years (20,917 days).
Specimen MMRF_2836_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab8416f5-1a10-48ea-9ac8-f861e832075c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2836_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2836_1_PB_WBC_C2_KHS5U_L16613; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fbbb34c-65af-4edf-8730-da89d151453f

The open-access MAF lists 160 somatic variants for this specimen: 66 protein-altering or splice-affecting, 21 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, 3'UTR 35, Silent 21, Intron 19, 5'UTR 10, RNA 5, Splice Region 4, Nonsense Mutation 3, Splice Site 3, 5'Flank 3, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767131816, COSV61360305; called by muse, mutect2, varscan2
- ALPP | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 31/202 reads (15%) | catalogued as rs766430979, COSV67395953; called by muse, mutect2, varscan2
- ARHGAP20 | c.1153T>C p.F385L | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1169514094; called by muse, mutect2, varscan2
- CCND1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs761266790; called by muse, mutect2, varscan2
- CYBB | c.565_568del p.I189Sfs*24 | Frame Shift Del (DEL) | VAF 22/30 reads (73%) | catalogued as rs886041312; called by pindel, varscan2
- EPHA3 | c.2030T>G p.F677C | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60703826; called by muse, mutect2, varscan2
- IGHV2-70 | c.286A>C p.K96Q | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs184904469; called by muse, varscan2
- IGHV2-70 | c.202T>C p.W68R | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572594558; called by muse, varscan2
- IGLL5 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs762998471, COSV73248971, COSV73251039; called by muse, mutect2, varscan2
- IGLV3-1 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as rs190667156; called by muse, mutect2
- KDM4B | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs370112708, COSV50269582; called by muse, mutect2, varscan2
- MYOM3 | c.2617G>A p.V873M | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs199972567, COSV100292736; called by muse, mutect2, varscan2
- NOS3 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1323257260; called by muse, mutect2, varscan2
- NPVF | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs537152473; called by muse, mutect2, varscan2
- OR2T3 | c.664T>A p.S222T | Missense Mutation (SNP) | VAF 80/442 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100613085; called by muse, mutect2, varscan2
- P3H2 | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1040473465, COSV60022715; called by muse, mutect2, varscan2
- PPME1 | c.27C>G p.H9Q | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs757643501; called by muse, mutect2, varscan2
- SH3BP4 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs373202308; called by muse, mutect2, varscan2
- TENM3 | c.7344G>A p.P2448= | Splice Region (SNP) | VAF 23/61 reads (38%) | catalogued as rs750809999; called by muse, mutect2
- UBN1 | c.3220G>A p.V1074I | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs191007074; called by muse, mutect2, varscan2
- WDR11 | c.2152T>C p.W718R | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746153833; called by muse, mutect2, varscan2
- WDR25 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs768269075, COSV58934708; called by muse, mutect2, varscan2
- ZSCAN20 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63685301; called by muse, mutect2, varscan2
- ABHD6 | c.526C>T p.L176= | Splice Region (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
- AKAP9 | c.4537G>C p.E1513Q | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- ATP6V0A4 | c.2049C>A p.N683K | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL9 | c.3482G>T p.G1161V | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- BCL9L | c.3644C>T p.P1215L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CADPS2 | c.3312G>A p.E1104= | Splice Region (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- CDO1 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CFAP70 | c.911G>T p.C304F | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- CHL1 | c.386-1G>T p.X129_splice | Splice Site (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- CP | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DGKB | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH6 | c.2480A>C p.Q827P | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- EIF3E | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- EYS | c.8483A>G p.K2828R (on ENST00000370621 / NM_001292009.1; = p.K2807R on NM_001142800.2) | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); called by muse, mutect2
- FLYWCH1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- GALNTL6 | c.1054G>T p.G352* | Nonsense Mutation (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- GRIP1 | c.2669T>C p.F890S (on ENST00000359742 / NM_001379345.1; = p.F838S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- IGHV1-69D | c.316A>G p.R106G | Missense Mutation (SNP) | VAF 88/140 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, varscan2
- IGLV1-51 | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, varscan2
- IGLV11-55 | c.216C>G p.Y72* | Nonsense Mutation (SNP) | VAF 67/187 reads (36%) | called by muse, mutect2, varscan2
- KDM5A | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LARP4 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MIER1 | c.631C>A p.Q211K (on ENST00000355356 / NM_001077701.3; = p.Q228K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MORC2 | c.2126T>A p.V709D (on ENST00000397641 / NM_001303256.3; = p.V647D on NM_014941.3) | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MUC16 | c.9454G>T p.A3152S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MYH2 | c.2180+6T>G | Splice Region (SNP) | VAF 43/218 reads (20%) | called by muse, mutect2, varscan2
- MYLK | c.2815T>G p.S939A | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); called by muse, mutect2
- MYO1E | c.-3_3+21del | Splice Site (DEL) | VAF 25/66 reads (38%) | called by mutect2, pindel
- NHSL2 | c.532A>G p.S178G (on ENST00000510661; = p.S544G on NM_001013627.2) | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- NMBR | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- NTN1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2
- OR52R1 | c.219C>G p.D73E | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAXBP1 | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- PTCHD3 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SMIM17 | c.346T>G p.F116V | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- STX5 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTR | c.337-1G>A p.X113_splice | Splice Site (SNP) | VAF 81/272 reads (30%) | called by muse, mutect2, varscan2
- UBXN8 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- WNT10A | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- WNT5A | c.1124A>G p.D375G | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- XIRP2 | c.5313A>C p.K1771N (on ENST00000628543; = p.K1946N on NM_152381.6) | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- ZNF354C | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- ZNF511 | c.655G>C p.G219R | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAM22 | c.972T>C p.S324= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs771685405; called by muse, mutect2, varscan2
- ARMC4 | c.1668C>T p.A556= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs761407359; called by muse, mutect2, varscan2
- CD44 | c.1002G>A p.P334= | Silent (SNP) | VAF 92/307 reads (30%) | catalogued as rs750767970; called by muse, mutect2, varscan2
- CFAP46 | c.5082G>A p.R1694= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs1193506653, COSV54159389; called by muse, mutect2, varscan2
- CFAP52 | c.1821C>T p.A607= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs538016170, COSV99556757; called by muse, mutect2, varscan2
- COL4A5 | c.1512T>A p.P504= | Silent (SNP) | VAF 52/75 reads (69%) | called by muse, mutect2, varscan2
- CRACD | c.2799C>T p.H933= | Silent (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- EIF3F | c.30T>A p.A10= | Silent (SNP) | VAF 80/219 reads (37%) | called by muse, mutect2, varscan2
- ESR1 | c.1425C>T p.I475= | Silent (SNP) | VAF 62/185 reads (34%) | called by muse, mutect2, varscan2
- HMGXB4 | c.582T>A p.L194= | Silent (SNP) | VAF 69/179 reads (39%) | called by muse, mutect2, varscan2
- IGLV8-61 | c.345G>A p.V115= | Silent (SNP) | VAF 60/155 reads (39%) | catalogued as rs544414653; called by muse, mutect2, varscan2
- KCNK16 | c.849C>T p.P283= | Silent (SNP) | VAF 39/117 reads (33%) | called by muse, mutect2, varscan2
- MOB3A | c.579C>T p.F193= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as rs976863022, COSV63865454; called by muse, mutect2, varscan2
- MYH2 | c.2377C>A p.R793= | Silent (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- PDE4B | c.1866T>C p.I622= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- PTPRM | c.459C>T p.N153= | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- RAG1 | c.282C>T p.N94= | Silent (SNP) | VAF 88/279 reads (32%) | catalogued as rs148700564; called by muse, mutect2, varscan2
- RANBP17 | c.3099G>A p.E1033= | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- RYR2 | c.5004G>T p.G1668= | Silent (SNP) | VAF 96/208 reads (46%) | catalogued as COSV100767576; called by muse, mutect2, varscan2
- WWP2 | c.1431G>T p.P477= | Silent (SNP) | VAF 49/88 reads (56%) | called by muse, mutect2, varscan2
- ZNF534 | c.1839T>C p.H613= (on ENST00000332323 / NM_001143939.3; = p.H600= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- ANKRD18B | c.-40G>A | 5'UTR (SNP) | VAF 15/57 reads (26%) | catalogued as rs1222526630; called by muse, mutect2, varscan2
- BCL7B | c.*372G>A | 3'UTR (SNP) | VAF 7/142 reads (5%) | catalogued as rs371070414; called by muse, mutect2
- BIRC5 | c.*142G>A | 3'UTR (SNP) | VAF 9/26 reads (35%) | catalogued as rs188097548; called by muse, mutect2, varscan2
- BPNT2 | c.*4010C>T | 3'UTR (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- CACNA1S | c.-7G>A | 5'UTR (SNP) | VAF 105/256 reads (41%) | called by muse, mutect2, varscan2
- CAMKV | c.639-45G>A | Intron (SNP) | VAF 71/193 reads (37%) | catalogued as rs1267644923; called by muse, mutect2, varscan2
- CAPZB | c.4-29172C>G | Intron (SNP) | VAF 43/116 reads (37%) | called by muse, varscan2
- CD9 | c.*101del | 3'UTR (DEL) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- COL8A1 | c.*2290C>G | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- CREB5 | c.*4304T>C | 3'UTR (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- DCAF8 | c.*456T>G | 3'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- DIO2 | c.*1610G>A | 3'UTR (SNP) | VAF 22/54 reads (41%) | catalogued as rs1056410048; called by muse, mutect2, varscan2
- EDEM3 | c.*3019A>T | 3'UTR (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- ELOA2 | c.*329C>A | 3'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- ENSA | c.*162T>C | 3'UTR (SNP) | VAF 71/276 reads (26%) | called by muse, mutect2, varscan2
- ERGIC1 | c.643-22A>G | Intron (SNP) | VAF 50/145 reads (34%) | called by muse, mutect2, varscan2
- GAD2 | c.*35-676G>C | Intron (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- GALNT15 | c.*167C>G | 3'UTR (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- GDF5 | c.*82G>T | 3'UTR (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- GULP1 | c.843+1849A>T | Intron (SNP) | VAF 87/256 reads (34%) | called by muse, mutect2, varscan2
- HSP90B3P | n.145G>T | RNA (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- IDI1 | c.*668C>G | 3'UTR (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- IL3 | c.*132G>A | 3'UTR (SNP) | VAF 12/33 reads (36%) | catalogued as rs769987306; called by muse, mutect2, varscan2
- KCNK13 | c.*730T>C | 3'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- KCNMB3P1 | n.2086G>A | RNA (SNP) | VAF 70/198 reads (35%) | called by muse, mutect2, varscan2
- LIAS | c.429-134T>A | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- LRRC34 | c.-1C>T | 5'UTR (SNP) | VAF 47/128 reads (37%) | catalogued as rs1449308754; called by muse, mutect2, varscan2
- LTB | c.162+164G>A | Intron (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- MAGEE2 | c.*376G>A | 3'UTR (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- MS4A3 | c.-15-30T>A | Intron (SNP) | VAF 113/347 reads (33%) | called by muse, mutect2, varscan2
- MSR1 | c.1033+3578A>C | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- MYLK | c.3703+13G>A | Intron (SNP) | VAF 25/67 reads (37%) | catalogued as rs373115085; called by muse, mutect2, varscan2
- NIPA1 | c.*4485G>A | 3'UTR (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- NKX6-3 | c.*530C>T | 3'UTR (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- NPTN | chr15:73633504 C>A | 5'Flank (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- OPN5 | c.*582G>T | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- OR7E5P | n.577C>A | RNA (SNP) | VAF 25/311 reads (8%) | called by muse, mutect2
- PARGP1 | n.1221A>C | RNA (SNP) | VAF 43/119 reads (36%) | called by muse, mutect2, varscan2
- PCDH10 | c.-343A>T | 5'UTR (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- PCGF3 | c.*40C>A | 3'UTR (SNP) | VAF 79/228 reads (35%) | called by muse, mutect2, varscan2
- PCLO | c.-275G>T | 5'UTR (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- PDXK | c.*5143G>T | 3'UTR (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- PPP3CA | chr4:101348457 A>G | 5'Flank (SNP) | VAF 107/255 reads (42%) | called by muse, mutect2, varscan2
- PRR34 | n.1608C>T | RNA (SNP) | VAF 76/224 reads (34%) | called by muse, mutect2, varscan2
- PTAR1 | c.86+1986A>T | Intron (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- PTGFR | c.*2494G>A | 3'UTR (SNP) | VAF 25/83 reads (30%) | catalogued as rs1160932010; called by muse, mutect2, varscan2
- RASSF2 | c.*3569G>A | 3'UTR (SNP) | VAF 6/10 reads (60%) | catalogued as rs981726041; called by muse, mutect2, varscan2
- RBM34 | c.365+323_365+324insA | Intron (INS) | VAF 43/121 reads (36%) | called by mutect2, pindel, varscan2
- RBM45 | c.-14T>C | 5'UTR (SNP) | VAF 64/182 reads (35%) | called by muse, mutect2, varscan2
- SAMD4A | c.*1822A>T | 3'UTR (SNP) | VAF 13/43 reads (30%) | catalogued as rs201493365, COSV51883562; called by muse, mutect2, varscan2
- SEPSECS | c.*504G>T | 3'UTR (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- SERPINB7 | c.*602C>A | 3'UTR (SNP) | VAF 25/66 reads (38%) | catalogued as rs1338874268; called by muse, mutect2, varscan2
- SH2D4B | chr10:80644457 G>A | 3'Flank (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- SLC25A21 | c.70+133G>T | Intron (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- SLC30A2 | c.*1280_*1289del | 3'UTR (DEL) | VAF 45/128 reads (35%) | called by mutect2, pindel, varscan2
- SRPX | c.-39C>T | 5'UTR (SNP) | VAF 45/75 reads (60%) | called by muse, mutect2, varscan2
- SUMF2 | c.592+35T>G | Intron (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- SYVN1 | c.659-13C>A | Intron (SNP) | VAF 69/157 reads (44%) | called by muse, mutect2, varscan2
- TAPBPL | c.-76T>G | 5'UTR (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- TDRD1 | c.3538+251T>C | Intron (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- TFG | c.580+32C>G | Intron (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- THAP2 | c.*2918T>C | 3'UTR (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- TMEM151A | c.-74G>A | 5'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- TRAPPC4 | c.*691C>T | 3'UTR (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- TRDN | c.794-1091G>A | Intron (SNP) | VAF 17/46 reads (37%) | catalogued as rs1178308243; called by muse, mutect2, varscan2
- UBOX5 | c.*296A>G | 3'UTR (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- UNC13C | chr15:54012874 G>T | 5'Flank (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- UNC5D | c.*459T>G | 3'UTR (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- USP44 | c.*1050A>G | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, varscan2
- VPS13A | c.-121G>T | 5'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- WDR90 | c.1557-42G>A | Intron (SNP) | VAF 72/196 reads (37%) | catalogued as rs774521194; called by muse, mutect2, varscan2
- WSB1 | c.*1064G>A | 3'UTR (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- YAP1 | c.*2075A>C | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
